Somatic mutation profile of tumor specimen MP2PRT-PANXLC-TMP1-A (aliquot MP2PRT-PANXLC-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANXLC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (750 days).
Specimen MP2PRT-PANXLC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb86db5-1e61-4a58-9f05-0f915b482e90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANXLC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANXLC-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcc23551-1ad1-4252-adaa-9d919b54b9d5

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 46/233 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 83/182 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.518T>A p.L173H | Missense Mutation (SNP) | VAF 40/1242 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as CM105358; called by muse, mutect2
- BEST2 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs751506190, COSV99244765; called by muse, mutect2, varscan2
- FAT2 | c.6148C>T p.R2050W | Missense Mutation (SNP) | VAF 124/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750353121; called by muse, mutect2, varscan2
- LRP2 | c.10652G>A p.R3551H | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs545303364, COSV55548085; called by muse, mutect2, varscan2
- MYH10 | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52601188; called by muse, mutect2, varscan2
- RELN | c.10189C>T p.R3397W | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403459087, COSV100634658, COSV58987283; called by muse, mutect2, varscan2
- SLITRK2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 58/1036 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.084); catalogued as rs1451408651, COSV59424099; called by muse, mutect2
- ZNF883 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 86/196 reads (44%) | catalogued as rs201148870; called by muse, mutect2, varscan2
- NHS | c.4328T>A p.M1443K | Missense Mutation (SNP) | VAF 205/503 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PPP1R2C | c.231T>A p.S77R | Missense Mutation (SNP) | VAF 52/639 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- PXDNL | c.603C>T p.H201= | Silent (SNP) | VAF 97/267 reads (36%) | catalogued as rs762791402, COSV62487842; called by muse, mutect2, varscan2
